TCGA case TCGA-FB-A7DR — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Pancreas; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d47e214d-efbc-436d-b928-303d1f5135c4

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 48 years; Vital status: Dead; Days to death: 353 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 48.3 years (17,649 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 353 days; Sites of involvement: Pancreas Head; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Tumor largest dimension diameter: 3 cm.
   Treatment given: Treatment type: Total Pancreatectomy.

Follow-up (2 entries)
- Days to follow up: 166 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 353.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Tobacco smoking onset year: 1993.
- Alcohol history: Yes; Alcohol intensity: Drinker; Alcohol drinks per day: 1; Alcohol days per week: 3.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FB-A7DR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,350 mg.
  Slide TCGA-FB-A7DR-01A-02-TSB: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FB-A7DR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FB-A7DR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Colloid (mucinous non-cystic) Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Tissue Biopsy; Lymph nodes examined: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Alcohol exposure intensity: Weekly Drinker; Alcohol consumption frequency: 3; Diabetes diagnosis indicator: No; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Cause of death: Pancreatic Cancer; Treatment outcome at TCGA followup: Progressive Disease.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: the PAAD EPC states that this case likely did not arise in the pancreas (ampullary or duodenal).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 353 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 353 days; disease-free interval: no event (censored), 353 days; progression-free interval: no event (censored), 353 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FB-A7DR-01A-21D-A33S-01): tumor purity 0.22, ploidy 1.48, whole-genome doublings 0.
